Somatic mutation profile of tumor specimen HCM-CSHL-0603-C18-06A (aliquot HCM-CSHL-0603-C18-06A-21D-A80U-36) from HCMI case HCM-CSHL-0603-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.7 years (25,459 days).
Specimen HCM-CSHL-0603-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1519c284-f762-4732-8d48-1976101f2835.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0603-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0603-C18-11A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31023d2e-5174-4038-8d81-15b268a2b6f0

The open-access MAF lists 137 somatic variants for this specimen: 99 protein-altering or splice-affecting, 36 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 36, Nonsense Mutation 11, Splice Region 2, Intron 1, 3'UTR 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4067C>G p.S1356* | Nonsense Mutation (SNP) | VAF 244/364 reads (67%) | catalogued as rs1554085480, COSV57325773, COSV57330189, COSV57333960; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MITF | c.940C>T p.R314* (on ENST00000448226 / NM_006722.3; = p.R214* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 69/233 reads (30%) | catalogued as rs104893746, CM960962, COSV58832470; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 476/608 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANP32D | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 170/343 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs755224166; called by muse, mutect2, varscan2
- AREL1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 78/260 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs748782547; called by muse, mutect2, varscan2
- ARFGAP1 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 434/855 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.179); catalogued as rs1199118666; called by muse, mutect2, varscan2
- BICRAL | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 89/557 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.465); catalogued as COSV58409047; called by muse, mutect2, varscan2
- BX276092.9 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 293/350 reads (84%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs932057518; called by muse, mutect2, varscan2
- C8orf34 | c.1393C>G p.L465V | Missense Mutation (SNP) | VAF 75/556 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1224787592; called by muse, mutect2, varscan2
- CATSPERG | c.2949G>T p.W983C | Missense Mutation (SNP) | VAF 231/398 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53052685; called by muse, mutect2, varscan2
- CCN1 | c.145G>C p.G49R | Missense Mutation (SNP) | VAF 375/509 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs376836267; called by muse, mutect2, varscan2
- CFAP299 | c.243G>A p.K81= | Splice Region (SNP) | VAF 131/244 reads (54%) | catalogued as rs1276417011; called by muse, mutect2, varscan2
- CYB5R4 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 207/534 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.582); catalogued as rs1290013499; called by muse, mutect2, varscan2
- ERCC4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs377014538, COSV100318824; called by muse, mutect2, varscan2
- FBXO34 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 244/332 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV58254186; called by muse, mutect2, varscan2
- FGF6 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 120/556 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs767850309, COSV57404471; called by muse, varscan2
- FRMD4A | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 46/564 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.738); catalogued as rs369326023; called by muse, mutect2
- GABRB2 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777977171; called by muse, varscan2
- GMEB2 | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 105/704 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs779093678; called by muse, mutect2, varscan2
- GPC6 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 224/322 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1357289814, COSV65494787, COSV65525111; called by muse, varscan2
- HIF1AN | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs757543034; called by muse, mutect2, varscan2
- HTR4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 662/783 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140360260; called by muse, mutect2, varscan2
- HYDIN | c.6394G>A p.E2132K | Missense Mutation (SNP) | VAF 96/377 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as rs373417090; called by muse, mutect2, varscan2
- IPO13 | c.2800C>T p.R934* | Nonsense Mutation (SNP) | VAF 99/257 reads (39%) | catalogued as rs1248953818; called by muse, mutect2, varscan2
- LENG8 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 472/898 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs770407646, COSV100458166; called by muse, mutect2, varscan2
- LMTK3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 380/708 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as rs1284386412; called by muse, mutect2, varscan2
- LRRK2 | c.7567C>T p.R2523* | Nonsense Mutation (SNP) | VAF 93/177 reads (53%) | catalogued as rs755698334; called by muse, mutect2, varscan2
- MAGEE1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 438/562 reads (78%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as rs781822926; called by muse, mutect2, varscan2
- MAGEL2 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 455/654 reads (70%) | SIFT deleterious, low confidence (0.02); catalogued as rs1002045692, COSV58568454; called by muse, mutect2, varscan2
- MMUT | c.1824G>A p.M608I | Missense Mutation (SNP) | VAF 182/469 reads (39%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51273902; called by muse, mutect2, varscan2
- MRPS2 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 157/453 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.035); catalogued as rs1276524120; called by muse, mutect2, varscan2
- MUC4 | c.13709G>A p.R4570Q (on ENST00000463781 / NM_018406.7; = p.R334Q on NM_004532.6) | Missense Mutation (SNP) | VAF 234/1092 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs767767811; called by muse, mutect2, varscan2
- NCKAP5 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 37/514 reads (7%) | catalogued as COSV58454726; called by muse, mutect2
- NPAS4 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 177/523 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as rs1172916397; called by muse, mutect2, varscan2
- NPHS1 | c.2399G>A p.R800H | Missense Mutation (SNP) | VAF 149/588 reads (25%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.616); catalogued as rs146400394; called by muse, mutect2, varscan2
- OR4K2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 104/561 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs748394926, COSV53848232; called by muse, mutect2, varscan2
- OTOP3 | c.247C>A p.L83M | Missense Mutation (SNP) | VAF 442/549 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172697; called by muse, mutect2, varscan2
- PARP9 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 43/529 reads (8%) | catalogued as rs756620968; called by muse, mutect2
- PIGN | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759600092, COSV104414650, COSV62948506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCH1 | c.3935G>A p.R1312H (on ENST00000340059 / NM_001130960.2; = p.R1304H on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/635 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs777459311, COSV58211499; called by muse, mutect2, varscan2
- PPM1D | c.1262C>G p.S421* | Nonsense Mutation (SNP) | VAF 235/290 reads (81%) | catalogued as COSV59959014; called by muse, mutect2, varscan2
- PRUNE1 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.542); catalogued as COSV99639533; called by muse, mutect2, varscan2
- PXDNL | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 170/1224 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759582960, COSV99080550; called by muse, mutect2, varscan2
- RBMXL3 | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 435/512 reads (85%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.522); catalogued as rs912004716; called by muse, mutect2, varscan2
- RYR1 | c.7029C>T p.G2343= | Splice Region (SNP) | VAF 250/486 reads (51%) | catalogued as rs138617219; called by muse, mutect2, varscan2
- RYR2 | c.6380G>A p.R2127Q | Missense Mutation (SNP) | VAF 261/368 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516547, CM1313841, COSV63669324, COSV63693748; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHROOM4 | c.55dup p.A19Gfs*8 | Frame Shift Ins (INS) | VAF 282/348 reads (81%) | catalogued as rs782677387; called by mutect2, varscan2
- SLC35C2 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 69/408 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs778808342, COSV54756000; called by muse, mutect2, varscan2
- SLC6A16 | c.2161C>A p.L721I | Missense Mutation (SNP) | VAF 130/416 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.81); catalogued as COSV60026828; called by muse, mutect2, varscan2
- SLITRK5 | c.152C>A p.A51E | Missense Mutation (SNP) | VAF 242/355 reads (68%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as rs1338203946; called by muse, mutect2, varscan2
- SPON1 | c.1768G>A p.A590T | Missense Mutation (SNP) | VAF 155/441 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.37); catalogued as rs782203330; called by muse, mutect2, varscan2
- SZT2 | c.3568G>A p.V1190I (on ENST00000634258 / NM_001365999.1; = p.V1133I on NM_015284.4) | Missense Mutation (SNP) | VAF 88/287 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as rs779500330; called by muse, mutect2, varscan2
- TMEM132D | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 157/602 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs942395156, COSV70592927; called by muse, mutect2, varscan2
- TMEM200C | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 65/292 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1356262863, COSV67309243; called by muse, mutect2, varscan2
- TNNT3 | c.328C>T p.R110C (on ENST00000397301 / NM_001367846.1; = p.R99C on NM_006757.4) | Missense Mutation (SNP) | VAF 88/269 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99548499; called by muse, mutect2, varscan2
- TSHZ2 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 424/803 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772650306, COSV61588904; called by muse, mutect2, varscan2
- VSTM2L | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 317/420 reads (75%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs757359740, COSV65096623; called by mutect2, varscan2
- ZNF773 | c.1270T>G p.F424V | Missense Mutation (SNP) | VAF 211/446 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56590949; called by muse, mutect2, varscan2
- ZNF804A | c.3445G>C p.G1149R | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100169403, COSV56449221; called by muse, mutect2
- ZSCAN22 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 119/500 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.243); catalogued as rs375935212; called by muse, mutect2, varscan2
- ABCC9 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 80/441 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- APBA1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 214/605 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- APPBP2 | c.307A>T p.R103W | Missense Mutation (SNP) | VAF 399/500 reads (80%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ARMC3 | c.1000A>T p.I334F | Missense Mutation (SNP) | VAF 110/406 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- BBS10 | c.1832A>C p.H611P | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- C2CD4C | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 169/736 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CDH22 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 167/1039 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CHST15 | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 135/411 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLIC6 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 131/538 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); called by muse, varscan2
- CORO7 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 125/603 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- DDX10 | c.1622_1630del p.T541_E544delinsK | In Frame Del (DEL) | VAF 85/270 reads (31%) | called by mutect2, pindel, varscan2
- DDX6 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 76/208 reads (37%) | called by muse, mutect2, varscan2
- DNAH8 | c.8473G>T p.G2825* | Nonsense Mutation (SNP) | VAF 162/392 reads (41%) | called by muse, mutect2, varscan2
- DOCK3 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 98/306 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- DRC3 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 71/287 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- EHBP1L1 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM3C | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 118/706 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GPD2 | c.1151G>A p.S384N | Missense Mutation (SNP) | VAF 226/276 reads (82%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IFNA14 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 52/200 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, varscan2
- IL6R | c.464A>G p.N155S | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITCH | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 104/862 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- KCNMB1 | c.73G>T p.V25L | Missense Mutation (SNP) | VAF 436/578 reads (75%) | SIFT tolerated (0.9); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRT85 | c.1322_1323del p.V441Efs*43 | Frame Shift Del (DEL) | VAF 58/276 reads (21%) | called by pindel, varscan2
- LYST | c.11296T>A p.L3766M | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MALRD1 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 85/438 reads (19%) | SIFT tolerated (0.68); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MICALL2 | c.636C>A p.C212* | Nonsense Mutation (SNP) | VAF 89/483 reads (18%) | called by muse, mutect2, varscan2
- RNF6 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 1090/1200 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RSRC1 | c.824A>T p.D275V | Missense Mutation (SNP) | VAF 102/574 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SCN9A | c.2790G>T p.E930D (on ENST00000303354; = p.E919D on NM_002977.3) | Missense Mutation (SNP) | VAF 108/485 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SLC13A1 | c.1581C>A p.F527L | Missense Mutation (SNP) | VAF 101/560 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- SLC9A7 | c.1852C>G p.P618A | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SNX13 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- SOCS6 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 136/404 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORCS3 | c.410C>G p.P137R | Missense Mutation (SNP) | VAF 210/831 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX13C | c.993C>A p.D331E | Missense Mutation (SNP) | VAF 227/270 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTC34 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 584/761 reads (77%) | SIFT tolerated (1); PolyPhen possibly damaging (0.691); called by muse, varscan2
- TTN | c.77689C>T p.H25897Y (on ENST00000591111; = p.H18473Y on NM_003319.4) | Missense Mutation (SNP) | VAF 106/518 reads (20%) | PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- XIRP1 | c.5119C>T p.Q1707* | Nonsense Mutation (SNP) | VAF 237/460 reads (52%) | called by muse, mutect2, varscan2
- ZSCAN16 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 192/453 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ACTL7B | c.435C>T p.H145= | Silent (SNP) | VAF 186/505 reads (37%) | catalogued as rs149121708, COSV65926845; called by muse, mutect2, varscan2
- AMER2 | c.918C>T p.A306= | Silent (SNP) | VAF 195/1368 reads (14%) | called by muse, mutect2, varscan2
- ATAD2B | c.138C>T p.S46= | Silent (SNP) | VAF 638/777 reads (82%) | called by muse, mutect2, varscan2
- ATP9A | c.342C>T p.A114= | Silent (SNP) | VAF 60/593 reads (10%) | catalogued as rs183613927, COSV100124745; called by muse, mutect2, varscan2
- BHLHE22 | c.915C>A p.R305= | Silent (SNP) | VAF 171/1388 reads (12%) | called by muse, mutect2, varscan2
- COL6A6 | c.5112A>G p.G1704= | Silent (SNP) | VAF 104/495 reads (21%) | called by muse, mutect2, varscan2
- DNAH8 | c.3786G>C p.V1262= | Silent (SNP) | VAF 121/325 reads (37%) | called by muse, mutect2, varscan2
- FBN3 | c.1098C>T p.F366= | Silent (SNP) | VAF 139/564 reads (25%) | catalogued as rs751393494, COSV54460543; called by muse, mutect2, varscan2
- GOLGA6L9 | c.231C>T p.G77= | Silent (SNP) | VAF 220/697 reads (32%) | called by muse, mutect2, varscan2
- GPR153 | c.183C>T p.I61= | Silent (SNP) | VAF 115/514 reads (22%) | catalogued as rs374113239; called by muse, varscan2
- HAUS6 | c.24T>A p.A8= | Silent (SNP) | VAF 115/308 reads (37%) | called by muse, mutect2, varscan2
- LAMA5 | c.4131C>T p.L1377= | Silent (SNP) | VAF 141/458 reads (31%) | catalogued as rs748356543; called by muse, mutect2, varscan2
- LCA5 | c.268A>C p.R90= | Silent (SNP) | VAF 112/587 reads (19%) | called by muse, mutect2, varscan2
- LRRK1 | c.5211G>A p.T1737= | Silent (SNP) | VAF 329/783 reads (42%) | catalogued as rs376774894; called by muse, mutect2, varscan2
- MSH3 | c.2274C>T p.N758= | Silent (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- NIM1K | c.639C>T p.G213= | Silent (SNP) | VAF 146/410 reads (36%) | catalogued as rs1368386873, COSV58143400; called by muse, mutect2, varscan2
- NPIPB11 | c.3372C>T p.P1124= | Silent (SNP) | VAF 93/1114 reads (8%) | catalogued as rs1203578167; called by muse, varscan2
- NT5DC3 | c.48G>A p.R16= | Silent (SNP) | VAF 198/826 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.13128C>T p.D4376= | Silent (SNP) | VAF 428/570 reads (75%) | catalogued as rs775668321, COSV52844840; called by muse, mutect2, varscan2
- OBSL1 | c.2697C>T p.I899= | Silent (SNP) | VAF 104/435 reads (24%) | catalogued as rs745830430; ClinVar: likely benign; called by muse, varscan2
- OR1L4 | c.363C>T p.I121= | Silent (SNP) | VAF 130/402 reads (32%) | catalogued as rs747303306, COSV52341060; called by muse, mutect2, varscan2
- PLXDC1 | c.1368G>A p.A456= | Silent (SNP) | VAF 71/360 reads (20%) | catalogued as rs61742536, COSV59551231; called by muse, mutect2, varscan2
- PTGER4 | c.258C>A p.P86= | Silent (SNP) | VAF 142/792 reads (18%) | called by muse, mutect2, varscan2
- PWWP2B | c.1266G>C p.A422= | Silent (SNP) | VAF 176/631 reads (28%) | catalogued as rs761975821; called by muse, mutect2, varscan2
- SCYL2 | c.2394A>C p.P798= | Silent (SNP) | VAF 327/586 reads (56%) | called by muse, mutect2, varscan2
- SETD1B | c.1050G>A p.S350= | Silent (SNP) | VAF 197/649 reads (30%) | catalogued as rs1008545789, COSV99930901; called by muse, mutect2, varscan2
- SHC4 | c.918C>T p.Y306= | Silent (SNP) | VAF 108/154 reads (70%) | catalogued as rs553983973, COSV60116557; called by muse, mutect2, varscan2
- SIGLEC14 | c.357C>T p.R119= | Silent (SNP) | VAF 197/359 reads (55%) | called by muse, mutect2, varscan2
- SOX11 | c.72C>T p.G24= | Silent (SNP) | VAF 390/513 reads (76%) | called by muse, mutect2, varscan2
- SPPL2A | c.6G>T p.G2= | Silent (SNP) | VAF 147/385 reads (38%) | called by muse, mutect2, varscan2
- SYNGR4 | c.282C>T p.A94= | Silent (SNP) | VAF 136/563 reads (24%) | catalogued as rs545305567, COSV61225447; called by muse, mutect2, varscan2
- TLR10 | c.1107C>T p.I369= | Silent (SNP) | VAF 80/327 reads (24%) | called by muse, mutect2, varscan2
- TRIM71 | c.1440C>T p.S480= | Silent (SNP) | VAF 271/548 reads (49%) | catalogued as rs753096691, COSV67472820; called by muse, mutect2, varscan2
- TTN | c.77688C>A p.G25896= (on ENST00000591111; = p.G18472= on NM_003319.4) | Silent (SNP) | VAF 108/514 reads (21%) | catalogued as COSV60313927; called by muse, mutect2, varscan2
- ZNF611 | c.1581A>G p.T527= | Silent (SNP) | VAF 99/416 reads (24%) | called by muse, mutect2, varscan2
- ZNF780A | c.714C>G p.R238= | Silent (SNP) | VAF 138/509 reads (27%) | called by muse, mutect2, varscan2
- BAD | c.*150T>G | 3'UTR (SNP) | VAF 67/302 reads (22%) | called by muse, mutect2
- SLC9A1 | c.1485+182G>T | Intron (SNP) | VAF 137/202 reads (68%) | catalogued as rs920230886; called by muse, mutect2, varscan2
